Somatic mutation profile of cancer-model specimen HCM-SANG-0284-C18-85A (3D Organoid; aliquot HCM-SANG-0284-C18-85A-01D-A78M-36), derived from the primary tumor of HCMI case HCM-SANG-0284-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0284-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26999de7-77b1-4a52-a114-158f70547347.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0284-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0284-C18-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/729a2980-7a6e-4e86-9e87-ad7a061090cc

The open-access MAF lists 143 somatic variants for this specimen: 98 protein-altering or splice-affecting, 25 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 25, Intron 11, RNA 4, Frame Shift Del 2, 5'UTR 2, 5'Flank 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 67/105 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55878215, COSV55881107, COSV55917331; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 65/100 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABRA | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 268/427 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs750305260; called by muse, mutect2, varscan2
- ADCY8 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53909347; called by muse, mutect2, varscan2
- AMER1 | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV57663072; called by muse, mutect2
- AP2A1 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV100571282; called by muse, mutect2
- CCDC168 | c.18224G>A p.R6075H | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs780108376, COSV100487700; called by muse, mutect2, varscan2
- CERCAM | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 40/588 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs111695514; called by muse, mutect2
- CNKSR2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 215/391 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759498814, COSV54249894; ClinVar: benign; called by muse, mutect2, varscan2
- CORIN | c.3079G>A p.V1027I | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs758207729, COSV99904040; called by muse, mutect2, varscan2
- CRAT | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1409754786; called by muse, mutect2, varscan2
- DCAF12L2 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.66); catalogued as COSV63582035; called by muse, mutect2, varscan2
- DDX55 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs1481946540, COSV104379737; called by muse, mutect2, varscan2
- DNAH7 | c.10996G>A p.E3666K | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs761386813, COSV56766886; called by muse, mutect2, varscan2
- EPHA5 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV56657172; called by muse, mutect2, varscan2
- GABRG1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250801324, COSV54961467; called by muse, mutect2, varscan2
- GBA2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs954541417; called by muse, mutect2, varscan2
- ITIH4 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); catalogued as rs1559480944; called by muse, mutect2, varscan2
- KARS1 | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 14/508 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1157260478; called by muse, mutect2
- KLHL18 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs773078483, COSV51746366; called by muse, mutect2, varscan2
- LATS2 | c.2888G>A p.G963E | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66878660; called by muse, mutect2, varscan2
- LRRC8E | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1300239043; called by muse, mutect2, varscan2
- MAST4 | c.6625G>A p.D2209N (on ENST00000403625 / NM_001164664.2; = p.D2020N on NM_015183.3) | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV55120102, COSV99843640; called by muse, mutect2
- MYO1G | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 162/176 reads (92%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs763720788, COSV51853574; called by muse, mutect2
- OBSCN | c.14665C>T p.R4889W | Missense Mutation (SNP) | VAF 345/714 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746013384; called by muse, mutect2, varscan2
- OLFM2 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 112/398 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs201189277, COSV99321874; called by muse, varscan2
- OR10R2 | c.14T>G p.L5R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV63768660; called by muse, mutect2
- PIANP | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as rs1381414649; called by muse, mutect2, varscan2
- PNPLA6 | c.1032C>T p.H344= (on ENST00000414982 / NM_001166111.2; = p.H296= on NM_006702.5) | Splice Region (SNP) | VAF 133/293 reads (45%) | catalogued as rs769241929; called by muse, mutect2, varscan2
- PPFIBP2 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs772240559, COSV55076168; called by muse, mutect2, varscan2
- PTH1R | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 165/355 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775797881, COSV57317330; called by muse, mutect2, varscan2
- PTPRC | c.2691A>C p.Q897H | Missense Mutation (SNP) | VAF 41/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61405854, COSV61412086, COSV61419400; called by muse, mutect2
- RBPJL | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 80/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393715236; called by muse, mutect2, varscan2
- RFC4 | c.959_963del p.S320* | Frame Shift Del (DEL) | VAF 51/131 reads (39%) | catalogued as rs1560089077; called by mutect2, pindel, varscan2
- RPRD2 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 114/205 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as rs201375427; called by muse, mutect2, varscan2
- SLC52A2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 129/379 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs371806077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATS1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 152/351 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895918148, COSV55822633, COSV55823090; called by muse, mutect2, varscan2
- SPIN2A | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 22/622 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1442410067; called by muse, mutect2
- ST6GAL2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 56/113 reads (50%) | PolyPhen benign (0.017); catalogued as rs775329379; called by muse, mutect2, varscan2
- SUSD6 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763345823; called by muse, mutect2, varscan2
- TBC1D13 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 216/365 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs759494731; called by muse, mutect2, varscan2
- TET3 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1188197678, COSV104434475; called by muse, mutect2, varscan2
- TFAP2A | c.862G>A p.V288I (on ENST00000482890; = p.V280I on NM_001032280.3) | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs755697313; called by muse, mutect2, varscan2
- TLR8 | c.673C>T p.R225C (on ENST00000218032 / NM_138636.5; = p.R243C on NM_016610.4) | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs757616604; called by muse, mutect2, varscan2
- TP53 | c.761dup p.I255Hfs*9 | Frame Shift Ins (INS) | VAF 215/299 reads (72%) | catalogued as COSV104370837; called by mutect2, pindel, varscan2
- TRGV8 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 94/411 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs1189813014; called by muse, mutect2
- TRIM51GP | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 182/292 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as rs571910105; called by muse, mutect2, varscan2
- TRPC4 | c.2666G>T p.R889L (on ENST00000379705 / NM_016179.4; = p.R894L on NM_003306.3) | Missense Mutation (SNP) | VAF 45/424 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs761582713, COSV100157457, COSV58994204; called by muse, mutect2, varscan2
- UBASH3B | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 141/466 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs764362576, COSV99418248; called by muse, mutect2, varscan2
- VWCE | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs747777007, COSV100076032, COSV57112874; called by muse, mutect2, varscan2
- VWF | c.7571C>T p.P2524L | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs374690023; called by muse, mutect2, varscan2
- VWF | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746810319, CM1111383, COSV54610419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM22 | c.1324C>A p.L442I | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ADM5 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AK5 | c.268T>A p.F90I (on ENST00000354567 / NM_174858.3; = p.F64I on NM_012093.4) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ALDH18A1 | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BMS1 | c.2338T>C p.Y780H | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BTK | c.1495C>A p.L499I | Missense Mutation (SNP) | VAF 347/664 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C8orf48 | c.258A>C p.K86N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CACNA1F | c.5354T>C p.L1785P | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNP | c.548_550del p.F183del | In Frame Del (DEL) | VAF 66/132 reads (50%) | called by mutect2, pindel, varscan2
- CDCA7 | c.389C>A p.A130E (on ENST00000347703 / NM_145810.3; = p.A209E on NM_031942.5) | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CGN | c.2563A>G p.N855D | Missense Mutation (SNP) | VAF 97/453 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DCLK1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 66/546 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNHD1 | c.8536G>C p.E2846Q | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- DNM1 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.333); called by muse, mutect2
- FAM120B | c.2439G>C p.K813N | Missense Mutation (SNP) | VAF 65/407 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- FLG | c.5329T>C p.S1777P | Missense Mutation (SNP) | VAF 57/632 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2
- GRM3 | c.1559A>G p.N520S | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- GTF3C2 | c.2380C>T p.H794Y | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- GZMA | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGHV7-81 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IMPG2 | c.2170C>G p.L724V | Missense Mutation (SNP) | VAF 27/372 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- KIAA2026 | c.1835T>A p.F612Y | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- LPAR4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- LZTS1 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MUC16 | c.16063C>T p.P5355S | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); called by muse, mutect2
- MUC19 | c.421T>G p.F141V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MYBPC2 | c.1663G>T p.V555L | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2
- MYO3A | c.840A>C p.E280D | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEK8 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 175/531 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN4X | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUDT15 | c.44del p.G15Efs*6 | Frame Shift Del (DEL) | VAF 64/654 reads (10%) | called by mutect2, pindel, varscan2
- NWD2 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); called by muse, mutect2
- OOSP1 | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OVCH1 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PEBP1 | c.173T>A p.L58H | Missense Mutation (SNP) | VAF 100/187 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- PPIG | c.1328A>G p.E443G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG6 | c.237T>G p.I79M | Missense Mutation (SNP) | VAF 210/352 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- SIX2 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- SSC5D | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM216 | c.432G>T p.R144S (on ENST00000515837 / NM_001173990.3; = p.R83S on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIM51 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- WDR90 | c.3874G>T p.E1292* | Nonsense Mutation (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- XIRP1 | c.5504G>T p.C1835F | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF385B | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ZNF837 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ABCA13 | c.13069T>C p.L4357= | Silent (SNP) | VAF 43/508 reads (8%) | catalogued as COSV101291390; called by muse, mutect2
- B3GNT5 | c.315C>T p.S105= | Silent (SNP) | VAF 84/124 reads (68%) | catalogued as rs750868890; called by muse, mutect2, varscan2
- C1QL4 | c.264C>A p.G88= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs1385477129; called by muse, mutect2, varscan2
- C2orf78 | c.2013C>T p.L671= | Silent (SNP) | VAF 85/175 reads (49%) | catalogued as COSV68517497; called by muse, mutect2, varscan2
- C3 | c.1557G>A p.L519= | Silent (SNP) | VAF 117/304 reads (38%) | called by muse, mutect2, varscan2
- CEP170B | c.4335G>A p.S1445= (on ENST00000453495; = p.S1374= on NM_015005.3) | Silent (SNP) | VAF 154/156 reads (99%) | catalogued as rs780628198; called by muse, mutect2, varscan2
- CMKLR1 | c.159C>T p.L53= (on ENST00000312143 / NM_001142344.2; = p.L51= on NM_004072.3) | Silent (SNP) | VAF 80/202 reads (40%) | catalogued as rs757850821; called by muse, mutect2, varscan2
- CSMD1 | c.9309G>T p.P3103= (on ENST00000520002; = p.P3102= on NM_033225.6) | Silent (SNP) | VAF 106/155 reads (68%) | catalogued as COSV59315534; called by muse, mutect2, varscan2
- GABBR1 | c.2773C>A p.R925= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100590247; called by muse, mutect2
- GAS2 | c.645C>T p.C215= | Silent (SNP) | VAF 60/190 reads (32%) | called by muse, mutect2, varscan2
- HCFC1 | c.5310C>G p.A1770= | Silent (SNP) | VAF 15/346 reads (4%) | called by muse, mutect2
- KIF9 | c.1068C>G p.V356= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs1054875746, COSV55519430; called by muse, mutect2, varscan2
- MPIG6B | c.186G>A p.P62= | Silent (SNP) | VAF 12/239 reads (5%) | called by muse, mutect2
- MUCL3 | c.1212T>C p.S404= (on ENST00000304311; = p.S1280= on NM_080870.4) | Silent (SNP) | VAF 69/124 reads (56%) | called by muse, mutect2, varscan2
- NOS3 | c.2466G>A p.A822= | Silent (SNP) | VAF 95/195 reads (49%) | catalogued as rs558767937; called by muse, mutect2, varscan2
- OR5T2 | c.855T>G p.T285= | Silent (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- OR8J3 | c.564T>G p.S188= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV56882180; called by muse, mutect2, varscan2
- PSMD1 | c.9C>G p.T3= | Silent (SNP) | VAF 94/195 reads (48%) | called by muse, mutect2, varscan2
- RYR2 | c.7762T>C p.L2588= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- SCN9A | c.4974C>T p.Y1658= (on ENST00000303354; = p.Y1647= on NM_002977.3) | Silent (SNP) | VAF 65/133 reads (49%) | catalogued as rs757858235, COSV57600994; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHISA7 | c.1254C>T p.P418= | Silent (SNP) | VAF 118/317 reads (37%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1218G>A p.S406= (on ENST00000517878 / NM_001286646.2; = p.S355= on NM_001080431.2) | Silent (SNP) | VAF 95/271 reads (35%) | catalogued as rs771261958, COSV99200974; called by muse, mutect2, varscan2
- SPINK5 | c.1509G>A p.V503= | Silent (SNP) | VAF 78/275 reads (28%) | called by muse, mutect2, varscan2
- TNFSF13B | c.411T>C p.G137= | Silent (SNP) | VAF 23/419 reads (5%) | called by muse, mutect2
- ZSCAN10 | c.1944G>A p.A648= (on ENST00000252463; = p.A703= on NM_032805.3) | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV99374334; called by muse, mutect2
- AGBL3 | c.418+18C>A | Intron (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- AMPH | c.1182+414A>C | Intron (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- BIVM-ERCC5 | c.3561+35G>A | Intron (SNP) | VAF 45/404 reads (11%) | called by muse, mutect2, varscan2
- DVL2 | c.1035-30C>T | Intron (SNP) | VAF 17/17 reads (100%) | catalogued as rs781405704, COSV50036761; called by muse, varscan2
- FRMD1 | chr6:168081509 T>G | 5'Flank (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- KL | c.1599+43T>C | Intron (SNP) | VAF 177/551 reads (32%) | called by muse, mutect2, varscan2
- LINC01164 | n.998G>A | RNA (SNP) | VAF 95/240 reads (40%) | catalogued as rs539672245; called by muse, mutect2, varscan2
- MIR181B1 | n.67G>T | RNA (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- MRRFP1 | n.676C>G | RNA (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- MTRR | c.56+47G>A | Intron (SNP) | VAF 137/442 reads (31%) | called by muse, mutect2, varscan2
- NACA | c.71-4387C>A | Intron (SNP) | VAF 103/235 reads (44%) | called by muse, mutect2, varscan2
- NMT2 | c.111-13426G>T | Intron (SNP) | VAF 169/283 reads (60%) | called by muse, mutect2, varscan2
- POMT1 | c.1339-184G>T | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- PPP1R3C | c.-16G>A | 5'UTR (SNP) | VAF 271/421 reads (64%) | catalogued as rs773657244; called by muse, mutect2, varscan2
- PTMA | c.46-890G>T | Intron (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- SNORD116-17 | chr15:25087852 T>C | 3'Flank (SNP) | VAF 65/125 reads (52%) | called by muse, mutect2, varscan2
- TMEM235 | c.-495G>A | 5'UTR (SNP) | VAF 103/357 reads (29%) | catalogued as rs1346048509; called by muse, mutect2, varscan2
- TP73-AS1 | n.1277C>T | RNA (SNP) | VAF 142/257 reads (55%) | catalogued as rs755690165; called by muse, mutect2, varscan2
- XIAP | c.*58G>A | 3'UTR (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- YBX3 | c.878+455C>T | Intron (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
